Somatic mutation profile of tumor specimen TCGA-HZ-8637-01A (aliquot TCGA-HZ-8637-01A-11D-2396-08) from TCGA case TCGA-HZ-8637, project TCGA-PAAD (Pancreatic Adenocarcinoma). Sex at birth: female; Vital status: Dead; Primary diagnosis: Infiltrating duct carcinoma, NOS; Tissue or organ of origin: Head of pancreas; AJCC pathologic stage: Stage IIB; Tumor grade: G3; Age at diagnosis: 76.5 years (27,929 days).
Specimen TCGA-HZ-8637-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 209f7014-764a-486a-96d1-fe9aca0090cc.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-HZ-8637-10A (Blood Derived Normal), aliquot TCGA-HZ-8637-10A-01D-2396-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/17f6412c-79f7-4d43-8002-47eb8763c277

The open-access MAF lists 32 somatic variants for this specimen: 21 protein-altering or splice-affecting, 10 silent, 1 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 21, Silent 10, Intron 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- TP53 | c.733G>A p.G245S | Missense Mutation (SNP) | VAF 95/445 reads (21%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs28934575, CM010463, CM900210, CM920674, COSV52661744, COSV52661877, COSV52713951, COSV52839866; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- ADAMTS14 | c.1009C>T p.R337C | Missense Mutation (SNP) | VAF 40/506 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.959); catalogued as rs775055593, COSV100941798; called by muse, mutect2
- CAPZA3 | c.208G>C p.V70L | Missense Mutation (SNP) | VAF 63/602 reads (10%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.987); catalogued as COSV99856790; called by muse, mutect2, varscan2
- CGB5 | c.145G>A p.V49I | Missense Mutation (SNP) | VAF 24/758 reads (3%) | SIFT tolerated (0.42); PolyPhen benign (0.316); catalogued as rs1222317523; called by muse, mutect2
- COL1A2 | c.2330G>A p.R777H | Missense Mutation (SNP) | VAF 36/452 reads (8%) | SIFT deleterious (0); PolyPhen possibly damaging (0.791); catalogued as rs746187799, COSV51967474; called by muse, mutect2
- CSRNP3 | c.352C>T p.R118W | Missense Mutation (SNP) | VAF 26/286 reads (9%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.861); catalogued as rs781384120, COSV100085856, COSV58774473; called by muse, mutect2
- FN1 | c.4843C>G p.Q1615E | Missense Mutation (SNP) | VAF 40/436 reads (9%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.993); catalogued as COSV100117971; called by muse, mutect2
- HECW1 | c.224C>T p.S75L | Missense Mutation (SNP) | VAF 49/446 reads (11%) | SIFT deleterious (0.04); PolyPhen benign (0.357); catalogued as rs368244752; called by muse, mutect2, varscan2
- HSF4 | c.1465A>G p.S489G (on ENST00000521374 / NM_001040667.3; = p.S459G on NM_001538.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 42/749 reads (6%) | SIFT tolerated, low confidence (0.13); PolyPhen benign (0.014); catalogued as COSV99220595; called by muse, mutect2
- IRS4 | c.155G>C p.G52A | Missense Mutation (SNP) | VAF 59/670 reads (9%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.007); catalogued as COSV100929672; called by muse, mutect2
- IRX4 | c.451C>T p.R151C | Missense Mutation (SNP) | VAF 69/516 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV51471007; called by muse, mutect2, varscan2
- MYH15 | c.4307A>G p.E1436G | Missense Mutation (SNP) | VAF 18/353 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.981); catalogued as COSV99844088; called by muse, mutect2
- NUDC | c.560T>C p.F187S | Missense Mutation (SNP) | VAF 26/256 reads (10%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.486); catalogued as COSV100345698; called by muse, mutect2
- OR2T34 | c.893G>A p.R298H | Missense Mutation (SNP) | VAF 64/580 reads (11%) | SIFT deleterious (0); PolyPhen benign (0.181); catalogued as rs774162085, COSV60899659; called by muse, mutect2, varscan2
- PDZD4 | c.1165G>A p.V389I | Missense Mutation (SNP) | VAF 19/422 reads (5%) | SIFT tolerated (0.2); PolyPhen benign (0.38); catalogued as COSV99381592; called by muse, mutect2
- PTPRZ1 | c.6367G>A p.D2123N | Missense Mutation (SNP) | VAF 68/766 reads (9%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.697); catalogued as COSV101100672; called by muse, mutect2
- ST18 | c.2051A>G p.E684G | Missense Mutation (SNP) | VAF 36/276 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); catalogued as COSV99390759; called by muse, mutect2, varscan2
- STX11 | c.790C>T p.R264W | Missense Mutation (SNP) | VAF 32/259 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.948); catalogued as COSV100845519; called by muse, varscan2
- SYTL4 | c.265C>T p.R89W | Missense Mutation (SNP) | VAF 168/1049 reads (16%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.487); catalogued as rs765370816, COSV99343247; called by muse, mutect2, varscan2
- TRANK1 | c.7946A>T p.E2649V | Missense Mutation (SNP) | VAF 15/151 reads (10%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.086); catalogued as COSV100084403; called by muse, mutect2
- DRP2 | c.1733T>C p.F578S | Missense Mutation (SNP) | VAF 34/1341 reads (3%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- ANKRD11 | c.7581C>T p.I2527= | Silent (SNP) | VAF 49/423 reads (12%) | catalogued as rs751599226, COSV99970339; called by muse, mutect2, varscan2
- ARHGEF11 | c.2754G>A p.K918= | Silent (SNP) | VAF 134/938 reads (14%) | catalogued as rs924375863, COSV100168871; called by muse, mutect2, varscan2
- ASPM | c.6222G>A p.Q2074= | Silent (SNP) | VAF 21/728 reads (3%) | catalogued as COSV54133859; called by muse, mutect2
- KCNU1 | c.2907C>T p.H969= | Silent (SNP) | VAF 62/771 reads (8%) | catalogued as rs752811947, COSV67753072; called by muse, mutect2
- LRRC43 | c.354G>T p.T118= | Silent (SNP) | VAF 16/147 reads (11%) | catalogued as rs770398014, COSV100336904, COSV60289611; called by muse, mutect2, varscan2
- POU4F3 | c.405G>A p.P135= | Silent (SNP) | VAF 35/379 reads (9%) | catalogued as rs145372405, COSV57942473; ClinVar: uncertain significance; called by muse, mutect2
- TBX22 | c.450A>G p.K150= | Silent (SNP) | VAF 113/585 reads (19%) | catalogued as COSV100960927; called by muse, mutect2, varscan2
- TECTA | c.2199C>T p.S733= | Silent (SNP) | VAF 210/959 reads (22%) | catalogued as rs397517145, COSV50699092; called by muse, mutect2, varscan2
- TEP1 | c.3972T>G p.S1324= | Silent (SNP) | VAF 24/234 reads (10%) | catalogued as COSV99403047; called by muse, mutect2, varscan2
- TFDP3 | c.1182C>T p.N394= | Silent (SNP) | VAF 204/1059 reads (19%) | catalogued as rs751698892, COSV59538635; called by muse, mutect2, varscan2
- ARFRP1 | c.418-501_418-500del | Intron (DEL) | VAF 17/110 reads (15%) | catalogued as rs1423189623; called by mutect2, pindel, varscan2
